Gene-level copy-number profile of tumor specimen HCM-BROD-0873-C43-01A from HCMI case HCM-BROD-0873-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.8 years (24,401 days).
Specimen HCM-BROD-0873-C43-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8c692548-806e-41c2-91a8-bfb93feeb89e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0873-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/862d020b-7099-4a88-b184-da8134d7c5ee

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 762; copy number 2: 13,069; copy number 3: 13,313; copy number 4: 29,211; copy number 5: 557; copy number 6: 1,975; copy number 7: 4; copy number 8: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–2): AL449423.1.
- chr9:64,439,346–64,466,498, 3 genes: SNX18P9, CR769776.2, CYP4F25P.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr17:2,049,908–2,063,241, 3 genes (within-gene range 0–4): MIR132, MIR212, HIC1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:59,821,124–59,821,433, 1 gene, copy number 11: AC107934.2.

Autosomal genes at a single copy (total copy number 1): 250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
